Somatic mutation profile of tumor specimen MP2PRT-PATDDK-TMP1-A (aliquot MP2PRT-PATDDK-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PATDDK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.3 years (1,919 days).
Specimen MP2PRT-PATDDK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42bbc1e9-2e27-43b3-86d6-b28dc2f15e0b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATDDK-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATDDK-NM1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54467434-0f5d-4c93-83aa-7e5461711520

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Frame Shift Ins 3, Nonsense Mutation 2, Silent 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BBS9 | c.1741C>A p.H581N (on ENST00000242067 / NM_001348036.1; = p.H541N on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/303 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV54187880; called by muse, mutect2, varscan2
- CNR1 | c.1213C>T p.R405* | Nonsense Mutation (SNP) | VAF 103/445 reads (23%) | catalogued as rs770859974, COSV62986433; called by muse, mutect2, varscan2
- HES6 | c.364delinsCC p.A122Pfs*16 | Frame Shift Ins (INS) | VAF 117/1108 reads (11%) | catalogued as COSV54525764; called by mutect2*, pindel, varscan2*
- MED12 | c.3230T>C p.L1077P | Missense Mutation (SNP) | VAF 215/586 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100378763; called by muse, mutect2, varscan2
- SOHLH1 | c.908C>T p.T303M | Missense Mutation (SNP) | VAF 75/545 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs748866419, COSV53681699; called by muse, mutect2, varscan2
- ZFP36L1 | c.417_418insAGGGGGC p.G140Rfs*43 | Frame Shift Ins (INS) | VAF 92/692 reads (13%) | catalogued as COSV60546037; called by mutect2, pindel, varscan2
- COCH | c.1813G>A p.G605S (on ENST00000216361 / NM_001347720.1; = p.G540S on NM_004086.3) | Missense Mutation (SNP) | VAF 32/248 reads (13%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- HES6 | c.365dup p.A123Cfs*15 | Frame Shift Ins (INS) | VAF 112/879 reads (13%) | called by mutect2, varscan2
- PDE3A | c.50G>T p.S17I | Missense Mutation (SNP) | VAF 111/734 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); called by muse, mutect2
- PPIL4 | c.148A>G p.I50V | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- PSMB11 | c.488T>C p.V163A | Missense Mutation (SNP) | VAF 233/633 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFHX4 | c.997A>C p.I333L | Missense Mutation (SNP) | VAF 202/528 reads (38%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ZNF875 | c.1239_1243del p.Y413* | Nonsense Mutation (DEL) | VAF 86/349 reads (25%) | called by pindel*, varscan2
- GOLGA6D | c.687A>G p.R229= | Silent (SNP) | VAF 7/618 reads (1%) | catalogued as rs772800857; called by muse, mutect2
- MXRA5 | c.6528G>A p.P2176= | Silent (SNP) | VAF 218/599 reads (36%) | catalogued as rs1188399848, COSV54246756, COSV99478045; called by muse, mutect2, varscan2
- TRBV27 | chr7:142715861 ins CCG | 3'Flank (INS) | VAF 106/178 reads (60%) | called by mutect2, pindel*, varscan2*
